CCDI case PBBVCS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/80010dc9-c15d-4b9d-9d43-dfac784edb05

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Neuroendocrine carcinoma, NOS: ICD-O-3 morphology code: 8246/3; Tissue or organ of origin: Appendix; Age at diagnosis: 16.5 years (6,023 days).

Biospecimens (2 samples)
- Sample 0DI6KI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI6KY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
